Surgical pathology report (de-identified scan), TCGA case TCGA-IM-A41Y, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Miami, specimen TCGA-IM-A41Y-01A (Primary Tumor).

[page 1 of 5]
Name:	XXX	Case #:	XX
Gender:	F	Collected:	XX
MRN:	XX	Received:	XX
Location:	XX	Reported:	XX
Physician:	XX	Copy To:	

Pathologic Interpretation:

A. RIGHT INFERIOR LEVEL FOR LYMPH NODE:

METASTATIC PAPILLARY THYROID CARCINOMA to one lymph node (1/1).

B. RIGHT ANTERIOR PARATRACHEAL MASS, RULE OUT LYMPH NODE VS PARATHYROID:

METASTATIC PAPILLARY THYROID CARCINOMA to one lymph node (1/1).

C. RULE OUT RIGHT INFERIOR PARATHYROID #1:

Minute fragment of parathyroid gland.

D. RIGHT THYROID LOBECTOMY WITH MODIFIED RADICAL NECK DISSECTION, (stitch marks superior margin, sternocleidomastoid muscle):

PAPILLARY THYROID CARCINOMA, DIFFUSE SCLEROSING VARIANT with predominant CLASSICAL VARIANT FEATURES and follicular tall cell variant components, 6.8 cm.

Negative for extrathyroidal extension.

Lymphovascular invasion present.

See Tumor Summary.

ICD-O3
carcinoma, papillary,
diffuse sclerosing variant
8350/3

E. CRICOTRACHEAL MEMBRANE:

No malignancy present.

Site: thyroid, NOS
C73.9 7-24-12
RD

F. RULE OUT RIGHT SUPERIOR PARATHYROID:

METASTATIC PAPILLARY THYROID CARCINOMA to one lymph node (1/1).

G. LEFT THYROID LOBECTOMY AND ISTHUSECTOMY:

PAPILLARY THYROID CARCINOMA, DIFFUSE SCLEROSING VARIANT WITH OVER 90% OF TALL CELL VARIANT, 2.6 cm.

[page 2 of 5]
It extends into the perithyroidal soft tissue (minimal extension).

There is lymphovascular invasion.

See Tumor Summary.

H. RIGHT PARATRACHEAL DISSECTION:

METASTATIC PAPILLARY THYROID CARCINOMA in one of seven lymph nodes (1/7).

Largest focus is 0.1 cm.

No extranodal extension.

I. RIGHT LEVEL 2B NECK DISSECTION:

Negative for carcinoma in eight lymph nodes (0/8).

Largest focus is 0.2 cm.

No extranodal extension.

AJCC: pT3, pN1a, pMX

SURGICAL PATHOLOGY CANCER CASE SUMMARY

Procedure: Total thyroidectomy with right neck dissection

Received: In formalin

Specimen Integrity: Fragmented

Specimen Size:

Right lobe: 8 x 8 x 4 cm

Left lobe: 4.5 x 3.0 x 1.8 cm

Specimen weight: 137 grams

Tumor Focality: Multifocal: Bilateral

DOMINANT TUMOR:

Tumor Laterality: Right lobe

Tumor Size: Greatest dimension: 6.8 cm

Histologic Type:

Papillary carcinoma

Variant, specify: Diffuse sclerosing variant

Architecture:

Classical (papillary)

Follicular

Cytomorphology:

Classical

Tall cell

Margins:

Margins uninvolved by carcinoma

Lymph-Vascular Invasion: Present

Extent: Focal (less than 4 vessels)

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

SECOND TUMOR:

Tumor Laterality: Left lobe

Tumor Size: Greatest dimension: 2.6 cm

Histologic Type: Papillary carcinoma

[page 3 of 5]
Variant, specify: Diffuse sclerosing variant
Architecture: Tall cell
Cytomorphology: Tall cell
Margins: Margins involved by carcinoma
Lymph-Vascular Invasion: Present
Extent: Extensive: (4 or more vessels)
Perineural Invasion: Not identified
Extrathyroidal Extension: Present
Extent: Minimal

Pathologic Staging (pTNM):

TNM Descriptors:

m (multiple primary tumors)

Primary Tumor (pT):

pT3: Tumor more than 4 cm limited to thyroid or any tumor with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

Regional Lymph Nodes (pN):

pN1a: Nodal metastases to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) lymph nodes

Number examined: 18

Number involved: 4

Distant Metastasis (pM):

Not applicable

NOTE: Some immunohistochemical antibodies are analyte specific reagents (ASRs) validated by our laboratory. These ASRs are clinically useful indicators that do not require FDA approval. These clones are used: ID5=ER, PgR 636=PR, A483=HER2, H-11=EGFR. All immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by Envision Method. The results are read by a pathologist as positive or negative.

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Electronically Signed Out By XX

Intraoperative Consultation

- A. Right inferior level and lymph node, FS: Metastatic carcinoma consistent with papillary thyroid origin
- B. Right anterior paratracheal mass rule out lymph node versus parathyroid, FS: Metastatic carcinoma consistent with papillary thyroid origin to lymph node parenchyma. Parathyroid gland tissue is not identified.
- C. Rule out right inferior parathyroid, FS: Parathyroid tissue
- E. Cricotracheal membrane, FS: No definitive malignancy
- F. Rule out right superior parathyroid, FS: Connective tissue with papillary thyroid carcinoma. No parathyroid gland present.

XX

Clinical History:

None Provided

Operation Performed

[page 4 of 5]
**Fee**

A: RIGHT INFERIOR LEVEL FOR LYMPH NODE, FS Frozen section x 1, FS Perm x 1,
Touch Prep Histology x 1

**B: RIGHT ANTERIOR PARATRACHEAL MASS, RULE OUT LYMPH NODE VS
PARATHYROID, FS** Frozen section x 1, FS Perm x 1, Touch Prep Histology x 1

C: RULE OUT RIGHT INFERIOR PARATHYROID #1, FS Frozen section x 1, FS Perm x 1,
Touch Prep Histology x 1, H&E, Recut x 1

**D: RIGHT THYROID LOBECTOMY WITH MODIFIED RADICAL NECK DISSECTION,
STITCH MARKS SUPERIOR MARGIN, STERNOCLEIDOMASTOID MUSCLE** H&E, Initial x
1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial
x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E,
Initial x 1, H&E, Initial x 1, H&E

E: CRICOTRACHEAL MEMBRANE, FS Frozen section x 1, FS Perm x 1, FS Deep 1 x 1,
Touch Prep Histology x 1, H&E, Recut x 1

F: RULE OUT RIGHT SUPERIOR PARATHYROID, FS Frozen section x 1, FS Perm x 1,
Touch Prep Histology x 1

G: LEFT THYROID LOBECTOMY AND ISTHMUSECTOMY H&E, Initial x 1, H&E, Initial x
1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

H: RIGHT PARATRACHEAL DISSECTION H&E, Initial x 1, H&E, Initial x 1

I: RIGHT LEVEL 2B NECK DISSECTION H&E, Initial x 1, H&E, Initial x 1

- A. Received fresh is a lymph node measuring 1.2 x 0.7 x 0.4 cm. Bisected and submitted in toto for frozen.
- B. Received is a portion of red tissue that measures 0.3 x 0.3 x 0.2 cm. In toto in one cassette for frozen.
- C. Received is a membranous portion of tissue measuring 0.1 x 0.1 x 0.1 cm. In toto in one cassette for frozen.
- D. Received in formalin is a right thyroid lobectomy and segment of muscle weighing 128 grams. The whole specimen measures 8.0 x 8.0 x 4.0 cm. There is a suture marking superior aspect of the sternocleidomastoid muscle. Resection margin is inked black. Cross section through the specimen shows a large firm papillary pale tan mass, measuring 6.8 x 5.0 x 3.5 cm, involving the entire thyroid lobe. A segment of the mass close to the muscle shows multi-loculated cut surface with hemorrhagic material. It is

[page 5 of 5]
well separated by a capsule. The mass does not appear to be extending beyond the thyroid. No lymph nodes were grossly identified. Sections submitted as follows:

Cassette #1 Muscle resection margin

Cassettes #2-17 Representative sections of the mass in relation with the margin (cassette #17 with section of the loculated mass in relation with muscle. The firm area of the mass (papillary) was submitted almost in toto)

E. Received fresh is a light brown tissue fragment less than 1 mm in diameter. In toto in one cassette or for frozen.

F. Received fresh is a light brown tissue fragment 1 mm in diameter. In toto in one cassette for frozen.

G. Received in formalin is a thyroid (left lobe) weighing 9 grams, measuring 4.5 x 3.0 x 1.8 cm. The capsule is brown and dusky, inked black. Cross section through the specimen shows a red-brown parenchyma. There is an ill-defined pale tan, markedly firm mass measuring 2.6 x 1.8 x 1.5 cm. The mass involves the isthmus and a portion of the left lobe. Also, there is additional well-circumscribed firm, pale tan nodule measuring 0.3 cm in diameter involving the middle aspect of the left lobe. Sections submitted as follows:

Cassette #1-6 The large mass submitted in toto (from isthmus to left lobe)

Cassette #7 The small mass in the middle aspect, submitted in toto

H. Received in formalin are multiple yellow-tan fibroadipose tissue fragments, measuring 4.0 x 3.0 x 1.0 cm in aggregate. Seven lymph nodes are grossly present measuring up to 0.3 x 0.2 cm in greatest dimensions.

Sections submitted as follows:

Cassette #1 Three lymph nodes in toto

Cassette #2 Four lymph nodes in toto

I. Received in formalin is a yellow-tan fibroadipose tissue fragment measuring 3.0 x 3.0 x 2.0 cm in aggregate. Six lymph nodes are present, measuring up to 1.0 x 0.6 cm in greatest dimension. Sections submitted as follows:

Cassette #1&2 Three lymph nodes in toto per cassette

XX

Source: NCI Genomic Data Commons file ac5d15f7-bac8-469e-8d17-38418a52d6db (TCGA-IM-A41Y.F8C456B1-F094-4661-86D2-E66F1C0BEE6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).